Somatic mutation profile of tumor specimen ALCH-B39D-TTP1-A (aliquot ALCH-B39D-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B39D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.5 years (27,940 days).
Specimen ALCH-B39D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48806eb3-19a5-4e69-a4ca-fd6461323ec0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B39D-NB1-A (Blood Derived Normal), aliquot ALCH-B39D-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82a2c815-aa74-460e-87c9-2b473cddbd09

The open-access MAF lists 24 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 7, Splice Site 3, 5'Flank 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 36/553 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- CNTNAP4 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 27/332 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs145844553; called by muse, mutect2
- DOCK6 | c.1006A>T p.I336F | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs1568258057; called by muse, mutect2
- MANBA | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1194057591; called by muse, mutect2
- RRAD | c.423G>A p.M141I | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs978895527; called by muse, mutect2, varscan2
- TFB1M | c.547-2A>G p.X183_splice | Splice Site (SNP) | VAF 10/350 reads (3%) | catalogued as COSV65699530; called by muse, mutect2
- ALDH8A1 | c.1158C>A p.C386* | Nonsense Mutation (SNP) | VAF 39/514 reads (8%) | called by muse, mutect2
- CACNA1D | c.2564A>G p.E855G (on ENST00000350061 / NM_001128840.3; = p.E875G on NM_000720.4) | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2
- DDX28 | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EHBP1 | c.113A>G p.D38G | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- KDM5C | c.2061_2061+19del p.X687_splice | Splice Site (DEL) | VAF 32/198 reads (16%) | called by mutect2, pindel
- NSG2 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2
- PAPOLB | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.104); called by muse, mutect2
- RBM10 | c.1950+1G>A p.X650_splice | Splice Site (SNP) | VAF 42/196 reads (21%) | called by muse, mutect2, varscan2
- ATP1A3 | c.3012C>T p.Y1004= (on ENST00000545399 / NM_001256214.2; = p.Y991= on NM_152296.5) | Silent (SNP) | VAF 7/130 reads (5%) | catalogued as rs372919447; called by muse, mutect2
- GMPPB | c.303A>T p.A101= | Silent (SNP) | VAF 17/208 reads (8%) | called by muse, mutect2
- KATNA1 | c.1416A>C p.S472= | Silent (SNP) | VAF 22/262 reads (8%) | catalogued as COSV59502101; called by muse, mutect2
- LAMB2 | c.3741C>G p.A1247= | Silent (SNP) | VAF 12/191 reads (6%) | called by muse, mutect2
- MC5R | c.669C>T p.P223= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs142471410, COSV61255888; called by muse, mutect2
- PLCL1 | c.2193G>A p.Q731= | Silent (SNP) | VAF 8/166 reads (5%) | catalogued as COSV70877189; called by muse, mutect2
- ZBTB40 | c.1956A>G p.K652= | Silent (SNP) | VAF 22/414 reads (5%) | called by muse, mutect2
- CYB5R2 | chr11:7674357 G>A | 5'Flank (SNP) | VAF 10/311 reads (3%) | called by muse, mutect2
- ERICH3 | c.603+1563G>T | Intron (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- SART3 | chr12:108561170 A>T | 5'Flank (SNP) | VAF 9/142 reads (6%) | catalogued as rs1244307161; called by muse, mutect2
